Surgical pathology report (de-identified scan), TCGA case TCGA-XU-A930, project TCGA-THYM (Thymoma), tissue source site University Health Network, specimen TCGA-XU-A930-01A (Primary Tumor).

[page 1 of 3]
ICD-O-3
Thymoma, type B3, malignant
8585/3
Site: Thymus C379
JN 4/2/14

Patient Name: .

MRN: .

DOB: .

Gender: M

Service: .

Visit #: .

Location: .

Facility: .

Collected: .

Resulted: .

Ordering MD: .

Surgical Pathology Consultation Report

SPECIMEN(S) RECEIVED

1. Thymus: Thymoma, resection of portion of innominate vein and wedge resection right upper lobe

DIAGNOSIS

Thymectomy, resection of portion of innominate vein and wedge resection of right upper lobe:

- Thymoma, WHO type B3, with invasion into adipose tissue.
- Tumor 7.0 cm in greatest diameter.
- Tumor adheres to but has not invaded into the lung.
- Painted resection margins negative for tumor.

SYNOPTIC DATA

Specimen Type:	Not specified
Specimen Size:	Greatest dimension: 15 cm Additional dimensions: 10.3 x 3.0 cm
Tumor Site:	Thymus
Tumor Size:	Greatest dimension: 7.0 cm Additional dimensions: 3.5 x 2.5 cm
Histologic Type:	Type B thymoma, B3 (epithelial, atypical, squamoid, well-differentiated thymic carcinoma)
Pathologic Staging:	Stage III: Macroscopic invasion of neighboring organs
Regional Lymph Nodes:	pNX: Cannot be assessed
Distant Metastasis:	Cannot be assessed
Margins:	Margins uninvolved by tumor Distance of tumor from closest margin: 1 mm
Invasion of Pulmonary Parenchyma:	Absent
Pleural Invasion:	Absent
Vascular (Small/Large Vessel) Invasion:	Absent

[page 2 of 3]
Department of Pathology

Patient Name:

MRN:

DOB:

Gender:M

Service:

Visit #:

Location:

Facility:

Collected:

Resulted:

Ordering MD:

COMMENT

This tumor is predominantly epithelioid type composed of sheets and nests of large polygonal cells with relatively uniform round nuclei. There is mild lymphocytic infiltrate throughout the tumor. Focally some tumor cells show prominent nucleoli, but there is no necrosis. Possible lymphatic vessel infiltration is noted focally at the tumor periphery (invasion front). Occasional mitotic figures are present. The tumor has invaded into the adipose tissue but has not crossed the visceral pleura elastica into the lung. The tumor cells stain positive for high molecular weight cytokeratin but negative for CD5 and EMA. Focally some of the lymphocytes are CD1a positive, although the majority is CD5 positive. Overall the histological appearances of the tumor cells, the presence of CD1a lymphocytes and negative CD5 staining of tumor cells are more consistent with a predominantly epithelioid type thymoma.

ELECTRONICALLY VERIFIED BY:

CLINICAL HISTORY

thymoma

GROSS DESCRIPTION

The specimen labeled with the patient's name and as "thymus: Thymoma, resection of portion of innominate vein and wedge resection right upper lobe", consists of a 15.0 x 10.3 x 3.0 cm irregular piece of soft fatty tissue, received fresh. There is a 7.0 x 3.5 x 2.5 cm firm, tan, irregularly shaped tumor within the specimen. An attached 4.5 x 2.7 x 1.1 cm wedge of lung tissue is adherent to the specimen, in apparent contiguity with the tumor. A 6.0 cm length staple line partially encircles the lung wedge. A 1.3 cm length x 0.2 cm diameter segment of innominate vein is identified. The proximal portion of the vessel appears to be incorporated within the mass, however, the vein margin is grossly free of tumour. The specimen is painted with silver nitrate. The tumor and uninvolved tissue are sampled for tissue banking. Representative sections are submitted as follows:

1A shaved tissue from lung wedge staple line

1B-1H tumor, 1B-1C with lung, 1G-1H with adjacent uninvolved tissue

Status: complete

Page: 2 of 3

[page 3 of 3]
Department of Pathology

Patient Name:

MRN:

DOB:

Gender:M

Service:

Visit #:

Location:

Facility:

Collected:

Resulted:

Ordering MD:

1I-10 tissue uninvolved by tumor

1P inominate vein resection margin en face

1Q proximal inominate vein, with tumour

Status: complete

Page: 3 of 3

Source: NCI Genomic Data Commons file c184ff67-0b26-47c7-a0fe-532e895af25b (TCGA-XU-A930.09A3C18C-6311-4540-8CE3-16532A05459C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).